Somatic mutation profile of tumor specimen C3N-01488-03 (aliquot CPT0118160009) from CPTAC case C3N-01488, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 54.3 years (19,817 days).
Specimen C3N-01488-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19113931-c987-450e-b1d3-556d0e0b20ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01488-31 (Blood Derived Normal), aliquot CPT0119390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c5f5f17-b5ad-4acf-9865-4a9b856b70cb

The open-access MAF lists 659 somatic variants for this specimen: 469 protein-altering or splice-affecting, 117 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 406, Silent 117, Intron 30, Nonsense Mutation 22, Frame Shift Del 15, Splice Site 14, 3'UTR 14, 5'UTR 10, RNA 10, Splice Region 9, 5'Flank 7, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 61/248 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MITF | c.791A>G p.Y264C (on ENST00000448226 / NM_006722.3; = p.Y158C on NM_000248.4) | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 26/183 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54748170; called by muse, mutect2, varscan2
- TTC7A | c.1204-2A>G p.X402_splice | Splice Site (SNP) | VAF 61/267 reads (23%) | catalogued as rs876657392, CS143012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.1755C>G p.S585R | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV100494247; called by muse, mutect2
- ABCG8 | c.1884+2T>C p.X628_splice | Splice Site (SNP) | VAF 80/468 reads (17%) | catalogued as COSV99699622; called by muse, mutect2, varscan2
- ACSL1 | c.578-2A>T p.X193_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as rs1239463728; called by muse, mutect2, varscan2
- ACSM1 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 61/289 reads (21%) | catalogued as rs867699184, COSV54634311; called by muse, mutect2, varscan2
- ACTN2 | c.2668G>T p.G890W | Missense Mutation (SNP) | VAF 216/535 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856853, COSV63976618; called by muse, varscan2
- ADAMTS14 | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64601321; called by muse, mutect2, varscan2
- ADAMTS20 | c.3238T>A p.W1080R | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67127775; called by muse, mutect2, varscan2
- ADCK1 | c.1349G>T p.S450I | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs1429941764, COSV53086980; called by muse, mutect2, varscan2
- AK7 | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 22/134 reads (16%) | catalogued as rs762440219; called by muse, mutect2
- ANXA11 | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs374621104; called by muse, varscan2
- CACNA1E | c.6671C>T p.P2224L (on ENST00000367573 / NM_001205293.3; = p.P2181L on NM_000721.4) | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62402433; called by muse, mutect2
- CADM3 | c.185G>T p.W62L (on ENST00000368125 / NM_001127173.3; = p.W96L on NM_021189.5) | Missense Mutation (SNP) | VAF 138/345 reads (40%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as COSV100930398, COSV63686674; called by mutect2, varscan2
- CADPS | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV51880555; called by muse, mutect2, varscan2
- CD40LG | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as CM011012; called by muse, mutect2, varscan2
- CFAP65 | c.4300C>G p.P1434A | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV58557966; called by muse, mutect2, varscan2
- CHD9 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV68298442; called by muse, varscan2
- CHODL | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54735956; called by muse, mutect2, varscan2
- CHRDL2 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs1203534517; called by muse, mutect2, varscan2
- CLP1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs539245351, COSV57054653; called by muse, mutect2, varscan2
- CLUH | c.1370G>T p.R457L (on ENST00000435359; = p.R495L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV70928411; called by muse, mutect2, varscan2
- CORO2B | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1279783418; called by muse, mutect2, varscan2
- CRB1 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM106993; called by muse, mutect2
- CXADR | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.266); catalogued as rs748145898; called by muse, mutect2
- DDI1 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56376386; called by muse, mutect2, varscan2
- DKK3 | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100485072; called by muse, mutect2, varscan2
- DOCK4 | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV101455456; called by muse, mutect2, varscan2
- DYM | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53985032; called by muse, mutect2, varscan2
- EHMT1 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100604139; called by muse, mutect2, varscan2
- ELOA2 | c.2165C>A p.A722E | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV55299180; called by muse, mutect2, varscan2
- ENPP7 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 182/454 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1263330435, COSV60386372; called by muse, mutect2, varscan2
- EYS | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100676870, COSV61001579; called by muse, mutect2, varscan2
- F5 | c.1439C>A p.T480N | Missense Mutation (SNP) | VAF 209/470 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV63120764; called by muse, mutect2, varscan2
- FAM71E2 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58483780; called by muse, mutect2, varscan2
- FAP | c.1970-1G>A p.X657_splice | Splice Site (SNP) | VAF 22/119 reads (18%) | catalogued as rs748519577; called by muse, mutect2, varscan2
- FBXO39 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1422245000; called by muse, mutect2, varscan2
- FCSK | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55376103; called by muse, mutect2, varscan2
- FLG2 | c.4199G>T p.G1400V | Missense Mutation (SNP) | VAF 126/352 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as rs753309247; called by muse, mutect2, varscan2
- FMNL2 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374304834; called by muse, varscan2
- FREM1 | c.3257A>G p.N1086S | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs754527354; called by muse, mutect2, varscan2
- GLI2 | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV58043097; called by muse, mutect2, varscan2
- GLRA4 | c.270G>C p.M90I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65457177; called by muse, mutect2, varscan2
- HEPACAM2 | c.134G>T p.R45I (on ENST00000394468 / NM_001039372.4; = p.R33I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs139778626; called by muse, mutect2, varscan2
- HFM1 | c.2642C>A p.T881N | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs369341064; called by muse, mutect2, varscan2
- HHEX | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs867605493, COSV51105793; called by muse, mutect2, varscan2
- HOXA11 | c.226C>A p.R76S | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs138059493; called by muse, mutect2, varscan2
- HSD11B1 | c.150G>C p.M50I | Missense Mutation (SNP) | VAF 72/515 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs537609626; called by muse, mutect2, varscan2
- IGLV7-43 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.753); catalogued as rs368992010; called by muse, mutect2, varscan2
- IL1R1 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs201495812; called by muse, mutect2, varscan2
- IL21R | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV104402061, COSV61971812; called by muse, mutect2, varscan2
- ITGA8 | c.210-1G>T p.X70_splice | Splice Site (SNP) | VAF 30/142 reads (21%) | catalogued as COSV65230576; called by muse, varscan2
- KLF13 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV56147544; called by muse, mutect2, varscan2
- KLRK1 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as rs141717786; called by muse, mutect2, varscan2
- KMT2B | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV99386351; called by muse, mutect2, varscan2
- KRTAP10-4 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 77/563 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100554810; called by muse, mutect2, varscan2
- LAMA4 | c.1275G>T p.K425N (on ENST00000230538 / NM_001105206.3; = p.K418N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs782618132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC1 | c.3508A>T p.T1170S | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1304662469; called by muse, mutect2
- LCE2D | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.028); catalogued as COSV64228990; called by muse, mutect2, varscan2
- LILRA1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs777824206, COSV52178121; called by muse, mutect2, varscan2
- LKAAEAR1 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs1391351314; called by muse, mutect2, varscan2
- MEX3C | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68530176, COSV68530493; called by muse, mutect2
- MGA | c.5932A>G p.K1978E (on ENST00000219905 / NM_001164273.1; = p.K1769E on NM_001080541.2) | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV54951736; called by muse, mutect2
- MGAM2 | c.4390C>A p.R1464S | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1416070278, COSV72176301; called by muse, mutect2, varscan2
- MUC16 | c.30872C>A p.T10291N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV67483365; called by muse, mutect2, varscan2
- MYH1 | c.4792G>T p.V1598L | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV56849830; called by muse, mutect2, varscan2
- MYO5C | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99955082; called by mutect2, varscan2
- NAV3 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs778435394, COSV99896853; called by muse, mutect2, varscan2
- NLRP4 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV100015827, COSV56719137; called by muse, mutect2, varscan2
- NOTCH3 | c.5101G>T p.A1701S | Missense Mutation (SNP) | VAF 101/285 reads (35%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.597); catalogued as COSV54633894; called by muse, mutect2, varscan2
- NRXN1 | c.4024G>T p.E1342* | Nonsense Mutation (SNP) | VAF 43/224 reads (19%) | catalogued as COSV60489661; called by muse, mutect2, varscan2
- NTNG1 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100903703; called by muse, mutect2, varscan2
- ODF2 | c.554G>T p.R185L (on ENST00000434106 / NM_153433.2; = p.R161L on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs780846935, COSV63547809; called by muse, mutect2, varscan2
- OR2T11 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV58186076; called by muse, mutect2, varscan2
- OR2Z1 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60691619; called by muse, mutect2
- OR51G2 | c.508A>G p.R170G | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58992682; called by muse, mutect2, varscan2
- OR5W2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs754041941, COSV60616626; called by muse, mutect2, varscan2
- OR8B12 | c.710T>G p.F237C | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1228090904; called by muse, mutect2
- OVCH1 | c.2717T>A p.I906N | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); catalogued as COSV58962418; called by muse, mutect2, varscan2
- PAK5 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62027689, COSV62037271; called by muse, mutect2, varscan2
- PAPPA2 | c.4585C>A p.P1529T | Missense Mutation (SNP) | VAF 44/562 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100867511; called by muse, mutect2
- PBX1 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs201029742, COSV63343357, COSV63346462; called by muse, mutect2, varscan2
- PCLO | c.6613A>T p.S2205C | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV61617678; called by muse, mutect2
- PCSK4 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.431); catalogued as rs1448271969; called by muse, mutect2
- POLQ | c.7571G>T p.G2524V | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99951319; called by muse, mutect2
- PP2D1 | c.674T>A p.V225D | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1215606051; called by muse, mutect2, varscan2
- PRADC1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs754139520; called by muse, mutect2, varscan2
- PTGER4 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs764176792; called by muse, mutect2, varscan2
- PTPRM | c.2018C>G p.A673G | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV59848745; called by muse, mutect2, varscan2
- PUS7L | c.1235G>C p.R412T | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs777009297, COSV61261102; called by muse, mutect2, varscan2
- RAPGEF2 | c.2573A>G p.N858S | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs766326195, COSV52426632; called by muse, mutect2, varscan2
- RBBP8 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1198682157; called by muse, mutect2, varscan2
- RHOXF2B | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.782); catalogued as COSV65054833; called by muse, mutect2, varscan2
- RIMBP2 | c.2367A>T p.L789F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99899711; called by muse, mutect2, varscan2
- RIMS2 | c.3724A>G p.I1242V | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.05); catalogued as rs758658343; called by muse, mutect2, varscan2
- RPIA | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52168247; called by muse, mutect2, varscan2
- RPL7A | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs782312134; called by muse, mutect2
- RTL9 | c.2155C>T p.L719F | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs764969366; called by muse, mutect2, varscan2
- RTN1 | c.1640C>A p.T547K | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs776096398, COSV50719684; called by muse, mutect2, varscan2
- SCN1A | c.2561G>T p.G854V (on ENST00000303395 / NM_001202435.3; = p.G843V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as CD061467; called by muse, mutect2, varscan2
- SERPINB9 | c.215C>G p.S72W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV66234414; called by muse, mutect2, varscan2
- SHISAL1 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745893699, COSV66987536; called by muse, mutect2
- SHISAL1 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.255); catalogued as rs758566309; called by muse, mutect2, varscan2
- SLC7A13 | c.637del p.Q213Kfs*15 | Frame Shift Del (DEL) | VAF 25/168 reads (15%) | catalogued as COSV99878795; called by mutect2, pindel, varscan2
- SLC8A3 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV63521457; called by muse, mutect2, varscan2
- SLCO2A1 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as COSV60487511; called by muse, mutect2, varscan2
- SORCS3 | c.2283del p.H761Qfs*45 | Frame Shift Del (DEL) | VAF 31/181 reads (17%) | catalogued as COSV100863744; called by mutect2, varscan2
- SORCS3 | c.2287del p.E763Rfs*43 | Frame Shift Del (DEL) | VAF 31/213 reads (15%) | catalogued as rs868844368, COSV63799442; called by mutect2*, pindel, varscan2*
- SP100 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs897277068; called by muse, mutect2, varscan2
- SPAG16 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 16/204 reads (8%) | catalogued as COSV59075127, COSV59120865, COSV59129802; called by muse, mutect2
- SPC25 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs779527436; called by muse, mutect2, varscan2
- SPEG | c.3763G>T p.A1255S | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs564998678; called by muse, mutect2, varscan2
- SPHKAP | c.3667C>A p.L1223M | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100763803; called by muse, mutect2, varscan2
- SRGAP3 | c.1675A>G p.R559G | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64530050; called by muse, mutect2, varscan2
- SULT2B1 | c.283G>A p.V95M (on ENST00000201586 / NM_177973.2; = p.V80M on NM_004605.2) | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs200176089; called by muse, mutect2, varscan2
- SYN2 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765973963; called by muse, mutect2, varscan2
- SYNM | c.3640A>G p.M1214V | Missense Mutation (SNP) | VAF 39/516 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs782734601, COSV100018611; called by muse, mutect2
- SYT1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54077562; called by muse, mutect2, varscan2
- TBC1D8B | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52183696; called by muse, mutect2, varscan2
- TENM3 | c.5226C>A p.N1742K | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV69309284; called by muse, mutect2, varscan2
- TET2 | c.4034A>G p.Y1345C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54398617; called by muse, mutect2
- TIMM44 | c.1145T>C p.M382T | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs1343337130; called by muse, mutect2
- TLNRD1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.476); catalogued as rs1269588738, COSV51256583; called by muse, mutect2, varscan2
- TNRC6A | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs764455500, COSV59369941; called by muse, mutect2
- TRAPPC8 | c.2971G>T p.V991L | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs763138470; called by muse, mutect2, varscan2
- TRPC3 | c.562G>T p.V188L (on ENST00000379645 / NM_001366479.2; = p.V115L on NM_003305.2) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as COSV99312369; called by muse, mutect2, varscan2
- TXNDC16 | c.606-2A>T p.X202_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99909184; called by muse, varscan2
- UNC13C | c.5912C>G p.T1971R | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); catalogued as COSV52873278, COSV99036651; called by muse, mutect2, varscan2
- USH2A | c.10637G>T p.G3546V | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56398523; called by muse, mutect2
- USP28 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1352870162; called by muse, mutect2, varscan2
- VXN | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1407714131; called by muse, mutect2, varscan2
- WASHC4 | c.438A>G p.E146= | Splice Region (SNP) | VAF 60/389 reads (15%) | catalogued as rs755238656; called by muse, mutect2, varscan2
- WASL | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as rs527876668; called by muse, mutect2
- ZFHX4 | c.7794C>A p.S2598R | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); catalogued as COSV50496940, COSV99266027; called by muse, mutect2, varscan2
- ZNF2 | c.643G>T p.D215Y (on ENST00000611147 / NM_001291605.2; = p.D202Y on NM_021088.4) | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV54638029; called by muse, mutect2, varscan2
- ZNF302 | c.788A>G p.N263S (on ENST00000627982; = p.N184S on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1264179200, COSV101416486; called by muse, mutect2
- ZNF354B | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV59366418; called by muse, mutect2, varscan2
- ZNF727 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV71647056; called by muse, mutect2, varscan2
- ZNF768 | c.1179G>T p.R393S | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63320359; called by muse, mutect2, varscan2
- ZNF98 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 99/304 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV63340739; called by muse, mutect2, varscan2
- ABCA3 | c.4907C>T p.P1636L | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC013489.1 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AC100868.1 | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTBL2 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADAMTS12 | c.3966G>T p.W1322C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ADSS2 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- AGBL1 | c.1862A>T p.N621I | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGMO | c.367G>T p.G123* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- AHNAK2 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- AKAP13 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.952); called by muse, mutect2
- AL031777.2 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ALPK2 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- ALPK3 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- ANK2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD26 | c.2919G>C p.Q973H | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- ANKRD36 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.976); called by muse, varscan2
- AP3D1 | c.2797A>G p.M933V | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP4E1 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP5Z1 | c.1916G>T p.R639M | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ARHGAP12 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGAP20 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.5218G>T p.G1740* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- ASMTL | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ASMTL | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF7IP | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- ATP13A1 | c.2336-3C>T | Splice Region (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- ATP13A4 | c.2517G>T p.L839= | Splice Region (SNP) | VAF 57/338 reads (17%) | called by muse, mutect2, varscan2
- B3GNT6 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAZ2A | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BPTF | c.7610A>G p.N2537S | Missense Mutation (SNP) | VAF 56/467 reads (12%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP2 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C12orf56 | c.1463A>G p.N488S (on ENST00000543942 / NM_001170633.2; = p.N328S on NM_001099676.3) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- C17orf67 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf127 | c.245del p.P82Qfs*58 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- C1orf141 | c.234-1G>T p.X78_splice | Splice Site (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- C1orf74 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 181/419 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- C4orf54 | c.3559T>A p.S1187T | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); called by muse, mutect2
- CACNA1A | c.5888C>A p.A1963E | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1G | c.5714A>T p.K1905M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1H | c.3215T>A p.L1072Q | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CACNA1H | c.5378A>T p.N1793I | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALN1 | c.229C>A p.L77M (on ENST00000329008 / NM_001017440.3; = p.L119M on NM_031468.4) | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CASQ2 | c.285T>A p.D95E | Missense Mutation (SNP) | VAF 37/429 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CBLB | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CC2D1A | c.1196A>G p.D399G | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- CCDC174 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CCIN | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CD1A | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CDC5L | c.2216G>T p.W739L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- CDH16 | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- CDH18 | c.781G>T p.V261F | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CDHR5 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CELSR3 | c.4309G>T p.D1437Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CENPJ | c.1808G>C p.R603T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- CEP41 | c.1103A>T p.Q368L | Missense Mutation (SNP) | VAF 68/414 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CFAP299 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CFAP46 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFAP47 | c.5262T>A p.S1754R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CHD5 | c.5797G>A p.G1933S | Missense Mutation (SNP) | VAF 63/301 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CHL1 | c.1756C>A p.Q586K (on ENST00000397491 / NM_001253387.1; = p.Q602K on NM_006614.4) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHP2 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CHRNA4 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 99/682 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CIAO2A | c.350A>T p.Y117F | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, varscan2
- CLCN6 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CLCNKB | c.1999T>A p.C667S | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC14A | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- CLK2 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 50/688 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2
- CNTN3 | c.2147A>G p.E716G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CNTN4 | c.2605G>T p.G869C | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CNTNAP2 | c.1871C>A p.P624H | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COASY | c.1538G>T p.S513I | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.299); called by muse, mutect2
- COBL | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- COG7 | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by mutect2, varscan2
- COL18A1 | c.3055G>A p.G1019R (on ENST00000359759 / NM_130444.3; = p.G784R on NM_030582.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- COL5A3 | c.3251C>A p.P1084H | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A1 | c.1741-5G>C | Splice Region (SNP) | VAF 76/453 reads (17%) | called by muse, mutect2, varscan2
- COPS7B | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBBP | c.5095G>T p.G1699C | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CROCC2 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- CRYBG2 | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.247); called by muse, mutect2
- CSMD1 | c.1666G>T p.A556S (on ENST00000520002; = p.A555S on NM_033225.6) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTCFL | c.1928G>T p.R643I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTNNA2 | c.810C>A p.H270Q | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP11B2 | c.1463T>G p.I488R | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CYP2F1 | c.1351A>T p.T451S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.134); called by muse, mutect2
- CYP2W1 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP4V2 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DBN1 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCAF4L2 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 94/418 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- DLGAP3 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH9 | c.4511C>A p.T1504K | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- DPYS | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 72/508 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAML1 | c.2485G>A p.A829T (on ENST00000321322; = p.A769T on NM_020693.4) | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- DUSP8 | c.821+1G>T p.X274_splice | Splice Site (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- DUSP8 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYRK4 | c.699+1G>T p.X233_splice | Splice Site (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- EFCAB3 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELN | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 108/559 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ELOA2 | c.1810T>A p.W604R | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELOA2 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EMSY | c.2723A>T p.H908L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); called by muse, varscan2
- EP400 | c.9253G>C p.G3085R | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ERC2 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2
- FAM107B | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM135B | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- FAM205A | c.3770C>G p.A1257G | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- FAM205A | c.2803C>A p.H935N | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM98B | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBRS | c.1106C>T p.P369L (on ENST00000287468; = p.P889L on NM_001105079.3) | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- FBXL22 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO38 | c.739A>T p.N247Y | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGF13 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGFR1 | c.1325T>C p.L442P (on ENST00000447712 / NM_023110.3; = p.L440P on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.398); called by muse, mutect2
- FKBP15 | c.1597C>T p.L533F | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLRT1 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FNDC7 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, varscan2
- GASK1B | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GDF10 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GFRAL | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GPATCH2 | c.1243C>T p.H415Y | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPIHBP1 | c.449C>A p.T150K | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- H1-8 | c.151C>A p.R51S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HCFC1 | c.3330G>T p.E1110D | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HDGFL2 | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2
- HEATR1 | c.519A>T p.L173F | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELZ | c.1026A>C p.L342F | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- HGH1 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HMCN2 | c.9349G>A p.A3117T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- HOXC10 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | called by muse, varscan2
- HS3ST4 | c.1024A>T p.N342Y | Missense Mutation (SNP) | VAF 90/441 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- HSD3B2 | c.542C>G p.T181S | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGF1R | c.1681G>T p.D561Y | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- IGKV2D-24 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- IGKV2D-30 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- IGSF9B | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ILDR2 | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ING3 | c.810G>C p.R270S | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- INPP4A | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS13 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQSEC3 | c.2483T>A p.V828E (on ENST00000538872 / NM_001170738.2; = p.V525E on NM_015232.1) | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- IRAK4 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ITSN1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KATNBL1 | c.779T>G p.I260R | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA4 | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.043); called by muse, mutect2
- KCNA4 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- KCNH2 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- KCNK15 | c.933C>G p.S311R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KCNMB2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, varscan2
- KCNQ3 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- KIF19 | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- KIF1A | c.3677G>T p.G1226V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF26B | c.4567C>A p.Q1523K | Missense Mutation (SNP) | VAF 178/436 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLHL1 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KLHL13 | c.994A>T p.R332W | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL36 | c.1449_1450del p.G484Lfs*9 | Frame Shift Del (DEL) | VAF 20/135 reads (15%) | called by pindel, varscan2
- LAMC3 | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 92/421 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- LGALS3BP | c.792dup p.A265Cfs*73 | Frame Shift Ins (INS) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- LIN28A | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.3234C>G p.D1078E | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC4B | c.651C>A p.C217* | Nonsense Mutation (SNP) | VAF 27/274 reads (10%) | called by muse, mutect2, varscan2
- LRRK1 | c.1995G>T p.Q665H | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- LRRTM1 | c.643C>A p.H215N | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- M1AP | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- MAGEB6B | c.848del p.P283Rfs*6 | Frame Shift Del (DEL) | VAF 39/129 reads (30%) | called by mutect2, pindel, varscan2
- MAL2 | c.462T>A p.I154= | Splice Region (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- MAP2 | c.1514A>T p.Q505L | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MAP3K13 | c.780del p.T261Qfs*7 | Frame Shift Del (DEL) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.3169G>C p.E1057Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MAS1L | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MASP1 | c.982A>T p.S328C | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAT2B | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- MCCC2 | c.1072+3A>G | Splice Region (SNP) | VAF 33/407 reads (8%) | called by muse, mutect2
- MDM4 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MFAP4 | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.3846G>T p.Q1282H | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, varscan2
- MKRN2OS | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MLEC | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MRC1 | c.3877del p.T1293Pfs*5 | Frame Shift Del (DEL) | VAF 47/313 reads (15%) | called by mutect2, pindel, varscan2
- MTFR2 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, varscan2
- MUC16 | c.29224G>T p.V9742L | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MYH4 | c.4070C>A p.A1357D | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MYH8 | c.5267A>G p.E1756G | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- MYH8 | c.4179-2A>T p.X1393_splice | Splice Site (SNP) | VAF 27/282 reads (10%) | called by muse, mutect2
- NCAM1 | c.1636G>A p.E546K (on ENST00000316851 / NM_181351.5; = p.E536K on NM_000615.7) | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NCF4 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 54/562 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- NDRG2 | c.224A>G p.Y75C (on ENST00000298687 / NM_001354570.1; = p.Y61C on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK10 | c.3274C>A p.P1092T | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NFATC2IP | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP6 | c.2475_2481del p.A826Wfs*2 | Frame Shift Del (DEL) | VAF 18/216 reads (8%) | called by mutect2, pindel
- NNT | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPTX2 | c.1034A>T p.K345M | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTN1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUDT16L1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- NUTM2F | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- OGDH | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OPRPN | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR10S1 | c.798C>A p.Y266* | Nonsense Mutation (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- OR14K1 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OR1C1 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR2M4 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4A5 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OR51B4 | c.717del p.S240Pfs*7 | Frame Shift Del (DEL) | VAF 23/159 reads (14%) | called by mutect2, pindel, varscan2
- OR5L2 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR5T2 | c.541A>T p.M181L | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6M1 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PAPPA2 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PCSK2 | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PDCD11 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- PEPD | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHYH | c.850_861del p.S284_C287del | In Frame Del (DEL) | VAF 59/430 reads (14%) | called by mutect2, pindel, varscan2
- PLEKHB2 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLPPR4 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- PLXNA4 | c.3825G>T p.Q1275H | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PNLIPRP3 | c.904A>T p.R302* | Nonsense Mutation (SNP) | VAF 31/179 reads (17%) | called by muse, mutect2, varscan2
- POM121L12 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); called by muse, mutect2
- POM121L12 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.283); called by muse, mutect2
- PPP1R10 | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PPP1R2 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PRDM10 | c.2571T>A p.H857Q | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRLHR | c.1078C>A p.H360N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, varscan2
- PROS1 | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 23/194 reads (12%) | called by mutect2, varscan2
- PRRC2C | c.1525A>T p.R509W (on ENST00000367742; = p.R507W on NM_015172.4) | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2
- PTCHD4 | c.1682G>T p.S561I | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PUS7L | c.2086A>T p.I696L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, varscan2
- QSER1 | c.3671A>T p.E1224V (on ENST00000399302; = p.E1353V on NM_001076786.3) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- RAB3GAP2 | c.434+1G>T p.X145_splice | Splice Site (SNP) | VAF 54/497 reads (11%) | called by muse, mutect2, varscan2
- RAD50 | c.1981G>T p.G661* | Nonsense Mutation (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
- RASEF | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- RASGEF1B | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- REG1B | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELN | c.9397T>A p.C3133S | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RIPOR2 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ROBO3 | c.973A>T p.T325S | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RPUSD1 | c.95A>T p.K32M | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- RRAGC | c.756A>T p.S252= | Splice Region (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- RYR3 | c.11143+5G>T | Splice Region (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- SAMD9L | c.2359T>A p.Y787N | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SBF2 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBNO2 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- SCEL | c.1335A>G p.Q445= (on ENST00000349847 / NM_144777.3; = p.Q425= on NM_003843.4) | Splice Region (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
- SCGB3A2 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SCN8A | c.2617G>T p.G873C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEL1L | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SFT2D1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- SFTPC | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SI | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SI | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLAMF6 | c.954T>A p.S318R (on ENST00000368057 / NM_001184714.2; = p.S317R on NM_052931.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC17A4 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 24/222 reads (11%) | called by muse, mutect2, varscan2
- SLC22A10 | c.1263G>T p.L421F | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC45A4 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SLCO5A1 | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLFNL1 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SLIT1 | c.450G>T p.R150S | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK1 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMARCA2 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- SNAP91 | c.*11-2A>T | Splice Site (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- SNAPIN | c.171A>T p.Q57H | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTG1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SNTG2 | c.925G>T p.G309* | Nonsense Mutation (SNP) | VAF 36/255 reads (14%) | called by muse, mutect2, varscan2
- SORCS1 | c.2385A>T p.K795N | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- SORCS1 | c.1534A>T p.R512W | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SOS2 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPAG17 | c.4892A>T p.H1631L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SPATA31A3 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 69/843 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- SPTA1 | c.3488C>A p.S1163Y | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- SPTA1 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.014); called by muse, mutect2
- SPTBN4 | c.5168T>C p.L1723P | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRRM4 | c.1757G>T p.R586M | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- STAP1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- STRC | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 50/550 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.845); called by muse, mutect2
- SUB1 | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- SYN1 | c.1728G>C p.K576N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TAS2R41 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TBC1D22A | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- TDRD15 | c.953A>C p.Q318P | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- TENM2 | c.2317del p.R773Afs*127 (on ENST00000518659 / NM_001122679.2; = p.R541Afs*127 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 45/228 reads (20%) | called by mutect2, varscan2
- TENM2 | c.4606G>T p.A1536S (on ENST00000518659 / NM_001122679.2; = p.A1297S on NM_001080428.3) | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TENM4 | c.4692del p.K1565Rfs*65 | Frame Shift Del (DEL) | VAF 47/258 reads (18%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.1033del p.E345Rfs*43 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- TGIF1 | c.257A>G p.N86S (on ENST00000330513 / NM_001374396.1; = p.N106S on NM_003244.4) | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- TIPRL | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TM9SF2 | c.1636A>G p.I546V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- TMC2 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.037); called by muse, mutect2
- TMEM131 | c.5111C>G p.S1704W | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM256 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMEM259 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TMEM59L | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TMEM65 | c.132del p.G45Afs*22 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- TMPPE | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- TOP2A | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2
- TRAF3IP1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAF3IP3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TRBV5-1 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TRIM49B | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 44/264 reads (17%) | called by muse, mutect2, varscan2
- TRIM49B | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPS1 | c.235G>T p.V79F (on ENST00000220888 / NM_001330599.2; = p.V92F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/436 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TTC17 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TTC3 | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TTN | c.36493A>G p.K12165E (on ENST00000591111; = p.K4741E on NM_003319.4) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.18323T>C p.I6108T (on ENST00000591111; = p.I5181T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/160 reads (17%) | PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TYW1 | c.1537A>T p.N513Y | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE3C | c.1261G>C p.V421L | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBN2 | c.2879A>G p.N960S | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- UNC13C | c.4856A>T p.Q1619L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- UPRT | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- USH2A | c.6116G>C p.G2039A | Missense Mutation (SNP) | VAF 27/502 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP31 | c.1700+1G>T p.X567_splice | Splice Site (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- USP40 | c.894A>T p.K298N | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- VPS13A | c.9432G>C p.E3144D | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VSX2 | c.101T>A p.I34N | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WNK2 | c.6671del p.P2224Qfs*92 (on ENST00000297954 / NM_001282394.1; = p.P2187Qfs*35 on NM_006648.3) | Frame Shift Del (DEL) | VAF 32/282 reads (11%) | called by mutect2, varscan2
- WWP1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XKR4 | c.1478G>T p.C493F | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLB | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZAP70 | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 28/349 reads (8%) | called by muse, mutect2
- ZBTB38 | c.1984A>G p.M662V | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFR | c.2998G>T p.A1000S | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZFR | c.2997G>T p.L999F | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF343 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 105/322 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF519 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF729 | c.3510C>A p.N1170K | Missense Mutation (SNP) | VAF 130/344 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNFX1 | c.5537G>T p.W1846L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABO | c.600C>G p.L200= | Silent (SNP) | VAF 70/422 reads (17%) | called by muse, mutect2, varscan2
- ACOX3 | c.1407G>A p.L469= | Silent (SNP) | VAF 37/176 reads (21%) | called by muse, mutect2, varscan2
- ACSM2B | c.1212C>A p.P404= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV61656848; called by muse, mutect2, varscan2
- ADAMTS14 | c.2217C>A p.A739= | Silent (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.33C>T p.H11= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1434A>C p.T478= (on ENST00000296862 / NM_001368115.2; = p.T410= on NM_153839.7) | Silent (SNP) | VAF 23/239 reads (10%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.1833C>A p.T611= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as COSV58415603; called by muse, mutect2, varscan2
- AJAP1 | c.675G>T p.T225= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV65450421; called by muse, varscan2
- AL031777.2 | c.330C>A p.P110= | Silent (SNP) | VAF 23/232 reads (10%) | catalogued as COSV100587095; called by muse, mutect2
- ANK2 | c.4236T>A p.P1412= | Silent (SNP) | VAF 43/221 reads (19%) | catalogued as COSV100001527; called by muse, mutect2, varscan2
- ARHGAP21 | c.3144C>A p.V1048= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.4212A>T p.T1404= | Silent (SNP) | VAF 78/480 reads (16%) | called by muse, mutect2, varscan2
- BACH1 | c.2040G>T p.L680= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, mutect2, varscan2
- BANP | c.1263G>T p.V421= (on ENST00000286122; = p.V393= on NM_017869.4) | Silent (SNP) | VAF 49/264 reads (19%) | called by muse, mutect2, varscan2
- CABP2 | c.387A>T p.G129= | Silent (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1899C>G p.A633= (on ENST00000356253 / NM_001366867.1; = p.A614= on NM_000722.4) | Silent (SNP) | VAF 74/322 reads (23%) | called by muse, mutect2, varscan2
- CCDC57 | c.2688T>C p.P896= | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- CDH16 | c.1977C>A p.A659= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- CDK14 | c.957T>C p.G319= (on ENST00000380050 / NM_001287135.2; = p.G301= on NM_012395.3) | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- CGGBP1 | c.336G>T p.L112= | Silent (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1122C>T p.S374= | Silent (SNP) | VAF 50/253 reads (20%) | catalogued as rs768261018; called by muse, mutect2, varscan2
- COL22A1 | c.4464C>A p.P1488= | Silent (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- CR1 | c.3723A>G p.T1241= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as rs553480368; called by muse, mutect2, varscan2
- CSN2 | c.531G>T p.L177= | Silent (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- CTC1 | c.1936C>A p.R646= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs780151711, COSV100236832; called by muse, mutect2, varscan2
- DAO | c.258C>T p.N86= | Silent (SNP) | VAF 24/410 reads (6%) | called by muse, mutect2
- DGKZ | c.2877C>T p.L959= (on ENST00000454345 / NM_001105540.2; = p.L771= on NM_003646.4) | Silent (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2
- DMRT1 | c.408C>A p.P136= | Silent (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- DNAH7 | c.3777C>T p.S1259= | Silent (SNP) | VAF 34/228 reads (15%) | catalogued as rs750915861, COSV100416798; called by muse, mutect2, varscan2
- DNAJC10 | c.2286G>A p.Q762= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs1254264057; called by muse, mutect2, varscan2
- DOCK2 | c.1953T>C p.D651= | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- EIF4A1 | c.90T>C p.I30= | Silent (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- EMILIN3 | c.1494A>T p.S498= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- EPX | c.1074C>A p.P358= | Silent (SNP) | VAF 39/301 reads (13%) | called by muse, mutect2, varscan2
- ERV3-1 | c.984A>G p.P328= | Silent (SNP) | VAF 34/373 reads (9%) | catalogued as rs757083023; called by muse, mutect2
- EVX1 | c.969G>T p.L323= | Silent (SNP) | VAF 72/304 reads (24%) | called by muse, mutect2, varscan2
- FAM181B | c.1099C>A p.R367= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV61300851; called by muse, mutect2, varscan2
- FAM47A | c.747G>T p.P249= | Silent (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- FAM83H | c.624A>T p.V208= | Silent (SNP) | VAF 66/401 reads (16%) | catalogued as rs535752010; called by muse, mutect2, varscan2
- FAT1 | c.8950C>T p.L2984= | Silent (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- FBN3 | c.2871C>T p.P957= | Silent (SNP) | VAF 34/464 reads (7%) | catalogued as rs1197113217, COSV54452554; called by muse, mutect2
- FCSK | c.168C>T p.S56= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as rs201023038; called by muse, mutect2, varscan2
- FLI1 | c.1260A>T p.S420= | Silent (SNP) | VAF 68/395 reads (17%) | catalogued as COSV55643578; called by muse, mutect2, varscan2
- FMNL2 | c.1035C>T p.T345= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, varscan2
- FNDC7 | c.216G>T p.T72= | Silent (SNP) | VAF 56/388 reads (14%) | called by muse, mutect2, varscan2
- GRAMD2B | c.414A>G p.L138= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- GRIN2A | c.573G>A p.V191= | Silent (SNP) | VAF 44/220 reads (20%) | called by muse, mutect2, varscan2
- HIF1A | c.1431A>G p.K477= | Silent (SNP) | VAF 17/237 reads (7%) | called by muse, mutect2
- HIVEP2 | c.5508C>T p.F1836= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- IGKV3D-7 | c.42G>T p.L14= | Silent (SNP) | VAF 59/362 reads (16%) | called by muse, mutect2, varscan2
- IGSF8 | c.228G>T p.L76= | Silent (SNP) | VAF 60/358 reads (17%) | called by muse, mutect2, varscan2
- ITIH5 | c.555G>A p.L185= | Silent (SNP) | VAF 51/298 reads (17%) | catalogued as rs774982548; called by muse, mutect2, varscan2
- KCNG1 | c.471G>T p.A157= | Silent (SNP) | VAF 51/341 reads (15%) | catalogued as COSV65369193; called by muse, mutect2, varscan2
- KMT2D | c.6846G>T p.R2282= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- KNL1 | c.4593A>G p.K1531= (on ENST00000346991 / NM_170589.5; = p.K1505= on NM_144508.5) | Silent (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- LRIT3 | c.1362G>T p.V454= | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- LRRTM1 | c.213C>T p.S71= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs149452279; called by muse, mutect2, varscan2
- LRTM1 | c.765G>T p.L255= | Silent (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- LYST | c.3165A>G p.L1055= | Silent (SNP) | VAF 38/426 reads (9%) | catalogued as rs763563678, COSV101089208; called by muse, mutect2
- MED15 | c.1848C>T p.Y616= (on ENST00000263205 / NM_001003891.3; = p.Y576= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- MEIS3 | c.832C>A p.R278= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as rs778163193, COSV100520618; called by muse, mutect2, varscan2
- MKI67 | c.8586A>G p.T2862= | Silent (SNP) | VAF 71/402 reads (18%) | called by muse, mutect2, varscan2
- MYH11 | c.1635G>A p.T545= | Silent (SNP) | VAF 73/309 reads (24%) | catalogued as rs773802963, COSV55542517; called by muse, mutect2, varscan2
- NCAM2 | c.666A>G p.A222= | Silent (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- NCOR2 | c.4287G>T p.P1429= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- NRXN3 | c.2805A>T p.G935= (on ENST00000335750 / NM_001330195.2; = p.G562= on NM_004796.6) | Silent (SNP) | VAF 25/143 reads (17%) | called by muse, varscan2
- OR11L1 | c.483G>C p.L161= | Silent (SNP) | VAF 36/410 reads (9%) | catalogued as COSV100869459; called by muse, mutect2
- OR14A2 | c.489C>A p.S163= | Silent (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- OR2W3 | c.585C>T p.I195= | Silent (SNP) | VAF 25/256 reads (10%) | catalogued as rs376214113, COSV64456210; called by muse, mutect2
- OR5L2 | c.171C>A p.T57= | Silent (SNP) | VAF 42/187 reads (22%) | catalogued as COSV65724731; called by muse, mutect2, varscan2
- OR5M11 | c.321A>T p.L107= | Silent (SNP) | VAF 34/191 reads (18%) | called by mutect2, varscan2
- OR6K6 | c.549T>A p.L183= (on ENST00000368144; = p.L159= on NM_001005184.1) | Silent (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2
- PCDH15 | c.4056G>A p.L1352= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as rs200926530, COSV100213344; called by muse, mutect2, varscan2
- PDE2A | c.615C>A p.A205= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- PIN4 | c.468A>G p.K156= (on ENST00000664196; = p.K131= on NM_006223.4) | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- PLCL1 | c.1251A>T p.L417= | Silent (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- PML | c.2091G>T p.L697= | Silent (SNP) | VAF 92/602 reads (15%) | called by muse, mutect2, varscan2
- POM121L12 | c.195C>T p.Y65= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- POTEE | c.2658T>G p.P886= | Silent (SNP) | VAF 109/718 reads (15%) | called by muse, varscan2
- PPP1R3A | c.1374A>T p.S458= | Silent (SNP) | VAF 47/189 reads (25%) | called by muse, mutect2, varscan2
- PTCHD4 | c.2385A>T p.T795= | Silent (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- PTPRD | c.3006C>A p.P1002= | Silent (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.1344A>G p.V448= | Silent (SNP) | VAF 37/182 reads (20%) | called by muse, mutect2, varscan2
- RBM34 | c.126A>G p.L42= | Silent (SNP) | VAF 67/268 reads (25%) | called by muse, mutect2, varscan2
- RGPD4 | c.3816A>T p.P1272= | Silent (SNP) | VAF 105/610 reads (17%) | called by muse, mutect2, varscan2
- RHEX | c.363T>A p.P121= | Silent (SNP) | VAF 104/291 reads (36%) | called by muse, mutect2, varscan2
- RPL5 | c.852G>A p.K284= | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as rs1368282046; called by muse, mutect2
- RYR2 | c.12030G>A p.V4010= | Silent (SNP) | VAF 28/189 reads (15%) | catalogued as COSV63706667; called by muse, mutect2, varscan2
- SALL3 | c.2256G>T p.V752= | Silent (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- SERPINB10 | c.483G>A p.Q161= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- SGIP1 | c.969T>G p.V323= | Silent (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- SLC10A2 | c.96G>T p.V32= | Silent (SNP) | VAF 55/177 reads (31%) | called by muse, mutect2, varscan2
- SLC12A5 | c.417C>A p.L139= (on ENST00000454036 / NM_001134771.2; = p.L116= on NM_020708.5) | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs1358161315; called by muse, mutect2, varscan2
- SLC17A1 | c.1323G>T p.V441= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- SLC19A2 | c.147C>G p.S49= | Silent (SNP) | VAF 42/552 reads (8%) | catalogued as rs1464446632; called by muse, mutect2
- SLCO4C1 | c.1725G>T p.A575= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV60513579; called by muse, mutect2, varscan2
- SPAG9 | c.2562A>T p.G854= (on ENST00000262013 / NM_001130528.3; = p.G840= on NM_003971.6) | Silent (SNP) | VAF 226/579 reads (39%) | called by muse, mutect2, varscan2
- STC2 | c.738C>A p.L246= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- STIL | c.3312A>T p.T1104= | Silent (SNP) | VAF 22/149 reads (15%) | called by muse, varscan2
- SULT4A1 | c.471C>A p.T157= | Silent (SNP) | VAF 26/198 reads (13%) | called by muse, mutect2, varscan2
- TANC2 | c.5367C>A p.I1789= | Silent (SNP) | VAF 34/313 reads (11%) | called by muse, mutect2, varscan2
- TBX20 | c.36C>A p.S12= | Silent (SNP) | VAF 48/208 reads (23%) | called by muse, mutect2
- TBX4 | c.738C>A p.A246= | Silent (SNP) | VAF 61/470 reads (13%) | called by muse, mutect2, varscan2
- TIAM2 | c.4722T>A p.S1574= (on ENST00000529824; = p.S1545= on NM_012454.3) | Silent (SNP) | VAF 53/296 reads (18%) | called by muse, mutect2, varscan2
- TLCD3A | c.321C>A p.S107= | Silent (SNP) | VAF 91/389 reads (23%) | called by muse, mutect2, varscan2
- TNFSF11 | c.420C>T p.I140= | Silent (SNP) | VAF 84/312 reads (27%) | catalogued as rs189501562; called by muse, mutect2, varscan2
- TNRC6B | c.1212C>T p.S404= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as rs1348614763; called by muse, mutect2
- TRAF3IP3 | c.1584C>T p.L528= | Silent (SNP) | VAF 18/279 reads (6%) | catalogued as rs1558034776; called by muse, mutect2
- TRBV7-1 | c.240C>A p.P80= | Silent (SNP) | VAF 45/179 reads (25%) | called by muse, mutect2, varscan2
- TRPC5 | c.285T>C p.Y95= | Silent (SNP) | VAF 44/127 reads (35%) | called by muse, mutect2, varscan2
- TRPM2 | c.3378C>A p.I1126= | Silent (SNP) | VAF 36/225 reads (16%) | called by muse, mutect2, varscan2
- VIPAS39 | c.183G>A p.G61= | Silent (SNP) | VAF 88/475 reads (19%) | catalogued as COSV53631311; called by muse, mutect2, varscan2
- WDR43 | c.69G>T p.P23= | Silent (SNP) | VAF 46/259 reads (18%) | catalogued as rs754464477; called by muse, mutect2, varscan2
- WSCD1 | c.1332C>T p.A444= | Silent (SNP) | VAF 45/250 reads (18%) | catalogued as rs1476948793; called by muse, mutect2, varscan2
- ZNF280A | c.564A>T p.P188= | Silent (SNP) | VAF 34/209 reads (16%) | called by muse, mutect2, varscan2
- ZNF35 | c.519T>C p.D173= | Silent (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- ZSCAN1 | c.117G>C p.L39= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV56603778; called by muse, mutect2, varscan2
- AAK1 | c.*10071T>A | 3'UTR (SNP) | VAF 62/350 reads (18%) | called by muse, mutect2, varscan2
- AC022148.1 | n.200C>T | RNA (SNP) | VAF 16/163 reads (10%) | catalogued as rs1338503744; called by muse, mutect2
- AC107023.1 | n.26-7166G>A | Intron (SNP) | VAF 20/163 reads (12%) | catalogued as rs1024118542; called by muse, mutect2, varscan2
- AC139769.1 | n.214-3574G>T | Intron (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- AC244197.3 | c.-1602A>T | 5'UTR (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- AGAP3 | c.224-1930G>C | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+17C>A | Intron (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- AL450442.1 | n.718C>A | RNA (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- APOF | c.-15C>A | 5'UTR (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2, varscan2
- ARHGDIA | c.*13G>A | 3'UTR (SNP) | VAF 28/458 reads (6%) | catalogued as COSV99482691; called by muse, mutect2
- ARHGEF4 | chr2:130916395 C>A | 5'Flank (SNP) | VAF 19/96 reads (20%) | catalogued as rs999252405; called by muse, mutect2, varscan2
- ARMC4 | c.*36A>T | 3'UTR (SNP) | VAF 37/206 reads (18%) | called by muse, mutect2, varscan2
- ATG16L1 | c.851+221G>A | Intron (SNP) | VAF 22/120 reads (18%) | catalogued as rs1207620809; called by muse, mutect2, varscan2
- BICD1 | c.213+68G>A | Intron (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- BTN2A3P | n.1706G>C | RNA (SNP) | VAF 54/255 reads (21%) | called by muse, mutect2, varscan2
- C16orf54 | c.*6C>T | 3'UTR (SNP) | VAF 58/361 reads (16%) | called by muse, mutect2, varscan2
- CD200 | c.-53C>A | 5'UTR (SNP) | VAF 36/218 reads (17%) | called by muse, mutect2, varscan2
- CFH | c.2957-29G>A | Intron (SNP) | VAF 46/189 reads (24%) | catalogued as rs56191748; called by muse, mutect2, varscan2
- CHCHD3 | c.170-10194A>G | Intron (SNP) | VAF 24/465 reads (5%) | called by muse, mutect2
- CHRNA7 | c.196-27G>A | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as rs755363492; called by muse, mutect2, varscan2
- CLRN1 | c.254-2062C>T | Intron (SNP) | VAF 51/225 reads (23%) | catalogued as rs1481366269; called by muse, mutect2, varscan2
- CLVS1 | c.-152+4247C>A | Intron (SNP) | VAF 31/193 reads (16%) | called by muse, mutect2, varscan2
- COG5 | c.1686+1506C>T | Intron (SNP) | VAF 62/307 reads (20%) | called by muse, mutect2, varscan2
- COX15 | c.*1094T>C | 3'UTR (SNP) | VAF 21/274 reads (8%) | catalogued as rs777588996; called by muse, mutect2
- CTDP1 | chr18:79679478 G>T | 5'Flank (SNP) | VAF 47/290 reads (16%) | catalogued as rs1193479749; called by muse, mutect2, varscan2
- DACH1 | c.*31G>T | 3'UTR (SNP) | VAF 50/154 reads (32%) | catalogued as COSV100498093; called by muse, mutect2, varscan2
- DLGAP1 | c.957+4428T>C | Intron (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- DNAJC11 | c.-2A>T | 5'UTR (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- FAM13C | c.-23G>A | 5'UTR (SNP) | VAF 32/192 reads (17%) | catalogued as rs771934634, COSV99513957, COSV99514024; called by muse, mutect2, varscan2
- FCF1 | chr14:74713091 ins A | 5'Flank (INS) | VAF 21/136 reads (15%) | called by mutect2, pindel, varscan2
- FHL1 | c.*428C>A | 3'UTR (SNP) | VAF 44/119 reads (37%) | called by muse, mutect2, varscan2
- GABRA2 | c.1059+5590C>T | Intron (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- GALNT11 | c.-95A>T | 5'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- GALNTL6 | c.139-177137G>T | Intron (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- GBP5 | c.1465+11A>T | Intron (SNP) | VAF 32/164 reads (20%) | called by muse, mutect2, varscan2
- HAUS7 | chrX:153471008 G>T | 5'Flank (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- HNF4A | c.-38A>T | 5'UTR (SNP) | VAF 100/279 reads (36%) | called by muse, mutect2, varscan2
- HPSE2 | c.1614-2059T>A | Intron (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+189G>T | Intron (SNP) | VAF 68/185 reads (37%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1642G>T | Intron (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- IRF1-AS1 | n.126A>G | RNA (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- KRT17P2 | n.614A>G | RNA (SNP) | VAF 50/391 reads (13%) | called by muse, mutect2, varscan2
- LINC02860 | n.1168T>A | RNA (SNP) | VAF 35/216 reads (16%) | called by muse, mutect2, varscan2
- MAGEB16 | c.-66-1587G>T | Intron (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- MAT2B | chr5:163503373 C>G | 5'Flank (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2, varscan2
- MIR7-3 | chr19:4769297 C>A | 5'Flank (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- MKS1 | c.916-37A>T | Intron (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+93011A>T | Intron (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- MSLNL | c.37+1333C>A | Intron (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- NDUFA5 | c.-5C>G | 5'UTR (SNP) | VAF 32/350 reads (9%) | called by muse, mutect2
- NPL | c.230+262G>T | Intron (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- OR7E5P | n.315C>A | RNA (SNP) | VAF 52/253 reads (21%) | called by muse, mutect2, varscan2
- OSCAR | c.*430C>A | 3'UTR (SNP) | VAF 16/115 reads (14%) | catalogued as COSV52927412; called by muse, mutect2, varscan2
- PAX2 | c.44-27T>A | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- PCARE | c.*20C>A | 3'UTR (SNP) | VAF 38/197 reads (19%) | catalogued as COSV100527617; called by muse, mutect2, varscan2
- PLSCR1 | c.355+64A>G | Intron (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227613 G>T | 3'Flank (SNP) | VAF 56/246 reads (23%) | called by muse, mutect2, varscan2
- PRSS56 | c.-13G>T | 5'UTR (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- RAG1 | c.*38G>T | 3'UTR (SNP) | VAF 38/182 reads (21%) | called by muse, mutect2, varscan2
- RORA | c.196+1421G>T | Intron (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- RPS17 | c.*303A>T | 3'UTR (SNP) | VAF 85/528 reads (16%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.109-2709T>C | Intron (SNP) | VAF 45/270 reads (17%) | catalogued as rs539766851; called by muse, mutect2, varscan2
- SCN4B | c.*992C>A | 3'UTR (SNP) | VAF 11/91 reads (12%) | catalogued as rs763488889; called by muse, mutect2
- SLC36A2 | c.1180+13G>A | Intron (SNP) | VAF 20/358 reads (6%) | catalogued as COSV100079346; called by muse, mutect2
- SORCS1 | c.*206G>T | 3'UTR (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- SOX8 | chr16:979101 G>A | 5'Flank (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1230G>T | RNA (SNP) | VAF 40/191 reads (21%) | catalogued as rs1017909401; called by muse, mutect2, varscan2
- SYT14 | chr1:210162882 T>A | 3'Flank (SNP) | VAF 78/214 reads (36%) | called by mutect2, varscan2
- TMEM68 | c.*16G>C | 3'UTR (SNP) | VAF 36/240 reads (15%) | called by muse, mutect2, varscan2
- TSPAN19 | c.-11G>C | 5'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2
- UBE2DNL | n.351G>T | RNA (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- UGT2B27P | n.262C>A | RNA (SNP) | VAF 51/257 reads (20%) | called by muse, mutect2, varscan2
- VWA3B | c.1837-879T>A | Intron (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
